Somatic mutation profile of tumor specimen C3L-05818-54 (aliquot CPT0341750002) from CPTAC case C3L-05818, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 47.9 years (17,486 days).
Specimen C3L-05818-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09f5f63a-215c-415b-89f8-3a6616af0475.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05818-50 (Buccal Cell Normal), aliquot CPT0341720002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/372a3b5b-9493-40e2-8ba0-52c1119215f5

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Frame Shift Ins 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 25/69 reads (36%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GATA2 | c.1151G>A p.R384K | Missense Mutation (SNP) | VAF 121/250 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV62003045; called by muse, mutect2, varscan2
- GBP1 | c.31A>G p.M11V | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs149801739; called by muse, mutect2, varscan2
- LMAN2L | c.1031G>T p.R344L | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV53840926; called by muse, mutect2, varscan2
- RIMS1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 151/358 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV53453337; called by muse, mutect2, varscan2
- RPAP2 | c.256C>G p.H86D | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV72509161; called by muse, mutect2, varscan2
- WT1 | c.1073_1074insGT p.V359Lfs*5 | Frame Shift Ins (INS) | VAF 109/297 reads (37%) | catalogued as COSV60065649, COSV60065719, COSV60065736, COSV60066137, COSV60067652, COSV60068117, COSV60069984, COSV60070623, COSV60071183, COSV60072151, COSV60083061, COSV60084162, COSV99070056, COSV99070061, COSV99070065; called by mutect2, pindel, varscan2
- CHD3 | c.5786_5793dup p.G1932Rfs*12 (on ENST00000330494 / NM_001005273.3; = p.G1898Rfs*12 on NM_005852.4) | Frame Shift Ins (INS) | VAF 55/138 reads (40%) | called by mutect2, varscan2
- DNMT3A | c.1584C>G p.Y528* | Nonsense Mutation (SNP) | VAF 102/233 reads (44%) | called by muse, mutect2, varscan2
- PLB1 | c.1034G>C p.R345T | Missense Mutation (SNP) | VAF 94/229 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- SLC2A14 | c.1559T>A p.V520D | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SORCS3 | c.1809G>T p.Q603H | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ADORA1 | c.759C>A p.L253= | Silent (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- CABLES2 | c.822G>T p.L274= | Silent (SNP) | VAF 35/103 reads (34%) | called by muse, mutect2, varscan2
- OPALIN | c.183G>A p.E61= | Silent (SNP) | VAF 48/88 reads (55%) | called by muse, mutect2, varscan2
- RNF139 | c.1674T>G p.A558= | Silent (SNP) | VAF 71/177 reads (40%) | called by muse, mutect2, varscan2
